CDDP_EAGLE case CDDP-ABLE — CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/eec6c979-1b41-42d7-941d-bd26eac4cba3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Year of birth: 1951.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Age at diagnosis: 53 years; Year of diagnosis: 2004; Days to diagnosis: 0 days; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 45 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Exposures
- Exposure type: Tobacco; Pack years smoked: 63; Exposure duration years: 42.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CDDP-ABLE-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample CDDP-ABLE-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
  Slide CDDP-ABLE-TTP1-B-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 26; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Protocol status: Completed; Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); Height cm at diagnosis: 170 cm; Weight kg at diagnosis: 60 kg; History neoadjuvant treatment: No; Tobacco smoking history indicator: 2; Tobacco smoking year started: 1962; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other Surgical Resection (Please Specify).
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
